CCDI case PBBZYK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fb2ca1b5-3166-4fd9-9a27-bf1aa5e03f21

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Neoplasm, benign: ICD-O-3 morphology code: 8000/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.8 years (3,213 days).

Biospecimens (2 samples)
- Sample 0DM4X6: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM4XK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
